Somatic mutation profile of tumor specimen TCGA-MQ-A4LV-01A (aliquot TCGA-MQ-A4LV-01A-11D-A34C-32) from TCGA case TCGA-MQ-A4LV, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 63.3 years (23,110 days).
Specimen TCGA-MQ-A4LV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1b21b53-7dfa-4c30-8822-8817f6b7315f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A4LV-10B (Blood Derived Normal), aliquot TCGA-MQ-A4LV-10B-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d70d7709-55d6-4cb4-b45b-744f4b9cf54c

The open-access MAF lists 45 somatic variants for this specimen: 39 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 35, Silent 6, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP12B | c.244C>T p.P82S (on ENST00000621682; = p.P94S on NM_001102467.2) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs769641721; called by muse, varscan2
- BAP1 | c.30C>A p.S10R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56241137; called by muse, mutect2, varscan2
- CCPG1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs150362667; called by muse, mutect2, varscan2
- CEP162 | c.3409A>G p.K1137E | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as rs1348369127; called by muse, mutect2, varscan2
- CRACDL | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.847); catalogued as COSV67407169; called by mutect2, varscan2
- CROT | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs755736735, COSV58977337; called by muse, mutect2, varscan2
- ESR2 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV50833435; called by muse, mutect2, varscan2
- GPR45 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.183); catalogued as COSV51524999; called by muse, mutect2, varscan2
- HEATR3 | c.400-1G>T p.X134_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV53529183; called by mutect2, varscan2
- LAMP3 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs968847932; called by muse, mutect2, varscan2
- MMP25 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as rs760635037; called by muse, mutect2, varscan2
- NF2 | c.1237A>T p.K413* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as CM950857; called by muse, mutect2, varscan2
- PRICKLE4 | c.923C>T p.S308L (on ENST00000359201; = p.S348L on NM_013397.6) | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs770715384; called by muse, mutect2, varscan2
- REPIN1 | c.1550G>A p.C517Y | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1252395521; called by muse, mutect2, varscan2
- SLC12A6 | c.3106G>A p.E1036K (on ENST00000354181 / NM_001365088.1; = p.E985K on NM_005135.2) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.418); catalogued as rs764764975, COSV51629422; called by muse, mutect2, varscan2
- USP7 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs1008492376, COSV100784157; called by muse, mutect2, varscan2
- VWF | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772466729, COSV54621841; called by muse, mutect2, varscan2
- AK2 | c.284G>T p.R95L (on ENST00000354858; = p.R137L on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ARHGAP35 | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- BTD | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- COL4A3 | c.1996C>T p.H666Y | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.3755G>A p.R1252K (on ENST00000409039; = p.R1191K on NM_207437.3) | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EML5 | c.5548G>C p.E1850Q (on ENST00000380664; = p.E1858Q on NM_183387.3) | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FLG | c.7679G>C p.S2560T | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- JAG1 | c.1121-1G>C p.X374_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- KCNC1 | c.452T>C p.M151T | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LATS2 | c.2149A>T p.R717W | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYD88 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NUFIP2 | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASEF | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- S100A9 | c.173T>A p.V58D | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDK1 | c.5776C>T p.H1926Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SETD2 | c.4966G>T p.V1656F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC22A16 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SPATA31D1 | c.2316T>A p.Y772* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- SPTBN1 | c.5305G>A p.G1769R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TAF1A | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TCHH | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZRANB3 | c.2081C>G p.P694R | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CLN8 | c.411C>A p.I137= | Silent (SNP) | VAF 44/226 reads (19%) | called by muse, mutect2, varscan2
- FBXL6 | c.1368C>T p.D456= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100095757; called by muse, mutect2, varscan2
- MYD88 | c.90G>T p.R30= | Silent (SNP) | VAF 31/133 reads (23%) | called by muse, mutect2, varscan2
- PPP1R15A | c.771C>T p.P257= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs373338552; called by muse, mutect2, varscan2
- REPS1 | c.2346C>A p.S782= (on ENST00000450536 / NM_001286611.2; = p.S781= on NM_031922.4) | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV99238887; called by muse, mutect2, varscan2
- S100A9 | c.174C>T p.V58= | Silent (SNP) | VAF 30/140 reads (21%) | called by muse, mutect2, varscan2
